Somatic mutation profile of tumor specimen C3N-02193-05 (aliquot CPT0210110006) from CPTAC case C3N-02193, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 79.4 years (28,999 days).
Specimen C3N-02193-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5150c74-583c-4441-a2f0-d07cbfb140c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02193-71 (Blood Derived Normal), aliquot CPT0210200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/042a6a25-0697-4efe-bd74-43c0fac331a8

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Nonsense Mutation 5, Intron 3, Frame Shift Ins 2, 5'UTR 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/398 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs1159092828; called by muse, mutect2
- BAZ2A | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 79/600 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.901); catalogued as rs1024089765; called by muse, mutect2, varscan2
- CCDC61 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs774939602, COSV99151542; called by muse, mutect2
- ENPP6 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs147979605; called by muse, mutect2
- FAT1 | c.1859A>T p.N620I | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs753881702; called by muse, mutect2, varscan2
- HNF4A | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 32/848 reads (4%) | catalogued as CD991895; called by muse, mutect2
- ITGAD | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 140/362 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV101210615; called by muse, varscan2
- LCE1B | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 162/461 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs371604336; called by muse, mutect2, varscan2
- LRP1 | c.4945G>A p.V1649M | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs756702192, COSV54524353; called by muse, mutect2, varscan2
- OR51I1 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100970179, COSV66507657; called by mutect2, varscan2
- PDXK | c.462C>T p.A154= | Splice Region (SNP) | VAF 57/304 reads (19%) | catalogued as rs776748861; called by muse, mutect2, varscan2
- PPFIBP1 | c.1867G>A p.A623T (on ENST00000318304 / NM_177444.3; = p.A617T on NM_003622.4) | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777162575; called by muse, mutect2, varscan2
- SI | c.1562A>G p.N521S | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1396138191; called by muse, mutect2, varscan2
- SIPA1L3 | c.3464G>A p.R1155Q | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs749979391, COSV55909376; called by muse, varscan2
- SPACA1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs1200509893, COSV52758884; called by muse, mutect2, varscan2
- TJP3 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as rs772949928; called by muse, mutect2, varscan2
- WDR47 | c.2438G>A p.R813H (on ENST00000369962 / NM_001142551.2; = p.R814H on NM_014969.5) | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371074191; called by muse, mutect2, varscan2
- XPOT | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.571); catalogued as rs769925840; called by muse, mutect2, varscan2
- ZDHHC8 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs554983212, COSV57711320; called by muse, mutect2, varscan2
- ZNF628 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as rs752284067, COSV99220297; called by muse, mutect2, varscan2
- ALDH1L2 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AP001781.2 | c.553C>G p.H185D | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- BEX4 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- BSN | c.665T>A p.M222K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- CYP1A1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM47A | c.2109G>T p.K703N | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- FATE1 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- IARS2 | c.268-1G>T p.X90_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2
- ICE1 | c.5740G>A p.A1914T | Missense Mutation (SNP) | VAF 84/475 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- MACF1 | c.3221_3222dup p.A1075* | Frame Shift Ins (INS) | VAF 74/305 reads (24%) | called by mutect2, pindel, varscan2
- MAST1 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC12 | c.2779G>T p.A927S (on ENST00000379442; = p.A784S on NM_001164462.1) | Missense Mutation (SNP) | VAF 135/1484 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.374); called by muse, mutect2
- NFKBIE | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX2-1 | c.955dup p.H319Pfs*90 | Frame Shift Ins (INS) | VAF 30/171 reads (18%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 88/570 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- RSPH6A | c.322A>T p.R108W | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); called by muse, mutect2
- SIPA1L3 | c.3251G>A p.W1084* | Nonsense Mutation (SNP) | VAF 123/590 reads (21%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3252G>A p.W1084* | Nonsense Mutation (SNP) | VAF 125/594 reads (21%) | called by muse, mutect2, varscan2
- SMTN | c.1763A>T p.D588V | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- STARD9 | c.11672C>A p.A3891D | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TBC1D8 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A1 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP36 | c.3259T>A p.F1087I | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ZBTB2 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF628 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1173G>A p.S391= | Silent (SNP) | VAF 82/316 reads (26%) | catalogued as rs764985052, COSV52817491; called by mutect2, varscan2
- AWAT1 | c.360C>T p.A120= | Silent (SNP) | VAF 29/706 reads (4%) | catalogued as rs201511922; called by muse, mutect2
- CALML5 | c.213G>A p.T71= | Silent (SNP) | VAF 31/623 reads (5%) | catalogued as rs935990248, COSV66702677; called by muse, mutect2
- CNTN1 | c.2934G>A p.A978= | Silent (SNP) | VAF 59/352 reads (17%) | catalogued as rs760832587, COSV61637545; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP2 | c.1377C>T p.H459= | Silent (SNP) | VAF 62/330 reads (19%) | catalogued as rs377678020; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIAPH2 | c.1575C>T p.I525= | Silent (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- GPR101 | c.1158C>T p.N386= | Silent (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- NFATC1 | c.2643G>A p.T881= (on ENST00000427363 / NM_001278669.2; = p.T868= on NM_172387.3) | Silent (SNP) | VAF 49/305 reads (16%) | catalogued as rs774500542; called by muse, mutect2, varscan2
- NR1H2 | c.963C>T p.H321= | Silent (SNP) | VAF 52/325 reads (16%) | catalogued as rs1188161848; called by muse, mutect2, varscan2
- SUPT6H | c.2076T>C p.F692= | Silent (SNP) | VAF 49/245 reads (20%) | catalogued as rs1345530276; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2484A>T p.P828= | Silent (SNP) | VAF 98/526 reads (19%) | called by muse, mutect2, varscan2
- TSPAN7 | c.360C>T p.F120= | Silent (SNP) | VAF 73/538 reads (14%) | called by muse, mutect2, varscan2
- ZNF628 | c.1923G>A p.L641= | Silent (SNP) | VAF 57/220 reads (26%) | called by muse, mutect2, varscan2
- CLPTM1L | c.1371+19C>G | Intron (SNP) | VAF 127/530 reads (24%) | called by muse, mutect2, varscan2
- ERC1 | c.2487+7669G>T | Intron (SNP) | VAF 59/265 reads (22%) | called by muse, mutect2, varscan2
- GCSAML | c.-17C>T | 5'UTR (SNP) | VAF 47/267 reads (18%) | catalogued as rs763443749, COSV100825986, COSV63577061; called by muse, mutect2, varscan2
- LONRF3 | c.1060-2436A>G | Intron (SNP) | VAF 53/293 reads (18%) | catalogued as rs746733981; called by muse, mutect2, varscan2
- MAMLD1 | c.*544A>G | 3'UTR (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- UBE2W | c.-15G>A | 5'UTR (SNP) | VAF 33/137 reads (24%) | catalogued as rs528120630; called by muse, mutect2, varscan2
